Somatic mutation profile of tumor specimen TARGET-20-PARZUU-04A (aliquot TARGET-20-PARZUU-04A-01D) from TARGET case TARGET-20-PARZUU, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,273 days).
Specimen TARGET-20-PARZUU-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 223ad8e2-143e-49f6-9338-cc5034104ee3.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARZUU-14A (Bone Marrow Normal), aliquot TARGET-20-PARZUU-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51415323-a1dc-4770-9894-ce604940083b

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 2, Frame Shift Ins 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT5B | c.2434C>T p.R812* | Nonsense Mutation (SNP) | VAF 118/293 reads (40%) | catalogued as rs1565212298, COSV58566478; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IKZF1 | c.1138A>T p.K380* | Nonsense Mutation (SNP) | VAF 26/66 reads (39%) | catalogued as COSV58792734; called by muse, mutect2, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- HASPIN | c.129C>T p.F43= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs775319727, COSV54001239; called by muse, mutect2, varscan2
- HDAC9 | c.*1088G>T | 3'UTR (SNP) | VAF 62/184 reads (34%) | called by muse, mutect2
